CPTAC case C3L-02358 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d73b1616-f3eb-462e-bf33-345872fee45b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1941; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 75.8 years (27,672 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,792 days (4.9 years); Progression or recurrence: yes; Days to last follow up: 1,792 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.4 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 17; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (6 entries)
- Days to follow up: 353 days; Disease response: With Tumor.
- Days to follow up: 693 days (1.9 years); Disease response: With Tumor.
- Days to follow up: 1,059 days (2.9 years); Disease response: With Tumor.
- Days to follow up: 1,448 days (4.0 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 398 days (1.1 years).
- Days to follow up: 1,448 days (4.0 years); Disease response: With Tumor.
- Days to follow up: 1,792 days (4.9 years); Disease response: With Tumor.

Other clinical attributes
- Weight: 87 kg; Height: 168 cm; BMI: 30.82; DLCO (% of predicted): 53; FEV1/FVC after bronchodilator (%): 59; FEV1/FVC before bronchodilator (%): 52; FEV1 after bronchodilator (% of reference): 66; FEV1 before bronchodilator (% of reference): 57.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 70; Cigarettes per day: 40; Tobacco smoking onset year: 1963; Tobacco smoking quit year: 1998; Exposure duration years: 35.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02358-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 320 mg; Time between excision and freezing: 29 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02358-23: Section location: Right Lower Lobe; Percent tumor nuclei: 75; Percent necrosis: 5.
- Sample C3L-02358-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 339 mg; Time between excision and freezing: 29 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02358-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
